Somatic mutation profile of tumor specimen 0DW744 from CCDI case PBCMJM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 13.0 years (4,731 days).
Specimen 0DW744: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c2277f2-dd9f-4627-a888-2224b32b8eb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW72K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77ad3ea2-8921-400b-9496-ccafeea78824

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Frame Shift Del 2, Silent 2, 5'Flank 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LAMA1 | c.7237G>T p.E2413* | Nonsense Mutation (SNP) | VAF 95/756 reads (13%) | catalogued as COSV67531466; called by muse, mutect2, varscan2
- ALCAM | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 19/677 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.039); called by muse, mutect2
- CACNA2D4 | c.704T>G p.V235G | Missense Mutation (SNP) | VAF 26/887 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- GPR135 | c.565T>G p.F189V | Missense Mutation (SNP) | VAF 22/526 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); called by muse, mutect2
- LYPLA1 | c.326_329del p.P109Lfs*70 | Frame Shift Del (DEL) | VAF 126/518 reads (24%) | called by mutect2, pindel, varscan2
- TNS4 | c.1895_1898del p.T632Mfs*73 | Frame Shift Del (DEL) | VAF 70/718 reads (10%) | called by pindel, varscan2
- BRD1 | c.1149T>G p.A383= | Silent (SNP) | VAF 29/672 reads (4%) | called by muse, mutect2
- OBI1 | c.39T>G p.T13= | Silent (SNP) | VAF 228/824 reads (28%) | catalogued as rs747722359; called by muse, mutect2, varscan2
- HBP1 | chr7:107168968 ins G | 5'Flank (INS) | VAF 55/243 reads (23%) | called by mutect2, pindel, varscan2
- ZFP91 | c.858-14G>C | Intron (SNP) | VAF 105/432 reads (24%) | called by muse, mutect2, varscan2
